Somatic mutation profile of tumor specimen TCGA-YL-A9WJ-01A (aliquot TCGA-YL-A9WJ-01A-11D-A377-08) from TCGA case TCGA-YL-A9WJ, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 47.4 years (17,322 days).
Specimen TCGA-YL-A9WJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13650a92-53e9-4bf7-826b-d78c4db60fb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YL-A9WJ-10A (Blood Derived Normal), aliquot TCGA-YL-A9WJ-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ab01c19-2d88-4a5f-83c2-2ccddb4b4c4a

The open-access MAF lists 26 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 16, Silent 5, Nonsense Mutation 4, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH11 | c.4825C>T p.R1609* | Nonsense Mutation (SNP) | VAF 3/20 reads (15%) | catalogued as rs1055960218, COSV100259726; ClinVar: likely pathogenic; called by muse, mutect2
- ADD2 | c.1150C>G p.R384G | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52456622, COSV52462275; called by muse, mutect2, varscan2
- ARSF | c.61C>A p.Q21K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as COSV100839565; called by muse, mutect2, varscan2
- ATP12A | c.2687G>A p.R896H | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs756031037, COSV54518726; called by muse, varscan2
- COL28A1 | c.1270G>A p.G424R | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101258803, COSV101258827; called by muse, mutect2
- FGA | c.1540C>A p.P514T | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as COSV100120581; called by muse, mutect2, varscan2
- FSTL5 | c.2427C>A p.Y809* | Nonsense Mutation (SNP) | VAF 35/146 reads (24%) | catalogued as rs765214111, COSV100059189; called by muse, mutect2, varscan2
- HFM1 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99646490; called by muse, mutect2, varscan2
- HFM1 | c.856T>G p.S286A | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99646492; called by muse, mutect2, varscan2
- LRP1B | c.11876C>A p.A3959E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs781576057, COSV101259043; called by muse, mutect2, varscan2
- METRNL | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100193783; called by muse, mutect2, varscan2
- MS4A14 | c.997C>A p.Q333K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV100280638; called by muse, mutect2, varscan2
- NPHP1 | c.721A>T p.K241* | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100338357; called by muse, mutect2
- OR10G8 | c.773A>G p.Y258C | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101461854; called by muse, mutect2, varscan2
- PCDH10 | c.1977G>C p.E659D | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.994); catalogued as COSV99994194; called by muse, mutect2, varscan2
- PCDH17 | c.3326G>A p.R1109Q | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs772772241, COSV100931688, COSV64974351, COSV64977549; called by muse, mutect2, varscan2
- RAP1GAP | c.1832C>T p.T611M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.556); catalogued as rs375344378; called by muse, mutect2, varscan2
- SCEL | c.709A>G p.N237D | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV100583099; called by muse, mutect2
- TRIM68 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 3/50 reads (6%) | catalogued as COSV100331692, COSV56167515; called by muse, mutect2
- ZNF142 | c.3125C>G p.P1042R (on ENST00000411696 / NM_001379660.1; = p.P842R on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV101376971; called by muse, mutect2, varscan2
- EHD2 | c.362_367del p.P121_F122del | In Frame Del (DEL) | VAF 7/45 reads (16%) | called by mutect2, pindel, varscan2
- FREM2 | c.1957C>T p.L653= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99749968; called by muse, mutect2
- MYPN | c.450T>C p.F150= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100590337; called by muse, mutect2, varscan2
- SHKBP1 | c.1779G>T p.L593= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as COSV99199025; called by muse, mutect2
- TENM1 | c.7836G>A p.L2612= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100950508; called by muse, mutect2, varscan2
- TSHZ1 | c.2841G>A p.V947= (on ENST00000580243 / NM_001308210.2; = p.V902= on NM_005786.6) | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100433862; called by muse, mutect2, varscan2
